Gene-level copy-number profile of tumor specimen ALCH-AEF6-TTP1-A from ALCHEMIST case ALCH-AEF6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.1 years (20,852 days).
Specimen ALCH-AEF6-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e96eb3c2-357d-4afb-a330-e85b3432ef55.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEF6-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/66d2eaf1-0b52-46ca-b6c1-ef4042823fa4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 75; copy number 1: 1,472; copy number 2: 54,783; copy number 3: 1,389; copy number 4: 642; copy number 5: 21; copy number 8: 1; copy number 12: 1; copy number 17: 2; copy number 21: 1; copy number 34: 1; copy number 35: 1.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:44,921,077–44,946,071, 11 genes (within-gene range 0–2): LINC01833, AC012354.9, AC012354.2, AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1, SIX3.
- chr2:130,129,621–130,145,134, 2 genes: MED15P9, CCDC74B.
- chr2:238,138,668–238,168,900, 3 genes: KLHL30, KLHL30-AS1, ERFE.
- chr3:126,973,065–127,037,392, 2 genes: AC011199.1, PLXNA1.
- chr3:129,315,392–129,326,225, 2 genes (within-gene range 0–2): H1-10-AS1, NUP210P3.
- chr5:443,175–524,449, 4 genes: EXOC3, PP7080, SLC9A3, SLC9A3-AS1.
- chr7:44,217,150–44,334,577, 1 gene: CAMK2B.
- chr7:128,830,406–128,862,626, 2 genes (within-gene range 0–2): FLNC, FLNC-AS1.
- chr10:23,343,957–23,345,181, 1 gene (within-gene range 0–2): AL606469.1.
- chr14:104,137,150–104,180,894, 2 genes: AL359399.1, KIF26A.
- chr15:32,585,524–32,615,158, 4 genes (within-gene range 0–2): AC123768.2, GOLGA8N, RN7SL286P, AC123768.1.
- chr15:41,825,099–41,894,053, 7 genes (within-gene range 0–2): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr16:2,131,851–2,133,204, 2 genes (within-gene range 0–1): Y_RNA, MIR4516.
- chr16:2,204,248–2,214,840, 4 genes: MLST8, BRICD5, PGP, AC009065.7.
- chr16:54,283,304–54,292,422, 3 genes: IRX3, AC018553.2, AC018553.1.
- chr16:56,351,886–56,353,524, 1 gene (within-gene range 0–2): AC009102.2.
- chr16:85,489,813–85,490,831, 1 gene: AC133540.1.
- chr17:75,818,815–75,820,055, 1 gene (within-gene range 0–2): AC087289.1.
- chr17:81,189,593–81,295,547, 8 genes: CEP131, AC027601.2, TEPSIN, AC027601.1, NDUFAF8, SLC38A10, AC027601.3, AC027601.4.
- chr17:82,371,400–82,382,690, 2 genes: UTS2R, AC132938.1.
- chr17:82,400,703–82,401,382, 1 gene (within-gene range 0–2): AC132938.2.
- chr19:1,609,290–1,652,615, 2 genes: TCF3, RNU6-1223P.
- chr22:29,720,003–29,731,833, 1 gene (within-gene range 0–2): CABP7.
- chr22:46,053,869–46,113,928, 1 gene (within-gene range 0–2): MIRLET7BHG.
- chr22:46,067,356–46,113,768, 5 genes (within-gene range 0–2): AL121672.2, MIR3619, MIRLET7A3, MIR4763, MIRLET7B.
- chr22:50,245,183–50,261,716, 2 genes: HDAC10, MAPK12.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 28 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:206,491,116–206,504,456, 2 genes, copy number 5 (within-gene range 3–5): C1orf147, AC244034.2.
- chr7:75,391,955–75,416,787, 3 genes, copy number 12–17 (within-gene range 2–17): AC211486.1, TRIM73, NSUN5P1.
- chr11:76,675,079–76,719,801, 2 genes, copy number 5 (within-gene range 2–5): AP001189.4, GUCY2EP.
- chr20:53,255,979–54,070,594, 14 genes, copy number 5 (within-gene range 2–5): AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756.
- chr21:43,092,956–43,168,646, 3 genes, copy number 5–34 (within-gene range 4–34): U2AF1, AP001631.2, MRPL51P2.
- chr21:43,159,066–43,162,277, 1 gene, copy number 5: AP001631.1.
- chr21:43,414,483–43,479,534, 3 genes, copy number 8–35 (within-gene range 3–35): SIK1, LINC00319, LINC00313.

Autosomal genes at a single copy (total copy number 1): 1,472. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
